Gene-level copy-number profile of tumor specimen TCGA-OR-A5K4-01A from TCGA case TCGA-OR-A5K4, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 64.3 years (23,481 days).
Specimen TCGA-OR-A5K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.516b3003-bda5-4b94-896a-5da9458b7570.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7912160b-498e-4732-ac41-71910effa2a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 82; copy number 2: 42,114; copy number 3: 255; copy number 4: 17,350; copy number 6: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K4-01A-11D-A29H-01): tumor purity 0.97, ploidy 1.29, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:151,615,773–152,875,991, 14 genes (within-gene range 0–2): RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11, MYCT1, HSPD1P16, VIP, LINC02840.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:9,505,180–9,530,524, 2 genes, copy number 6: LAMP5-AS1, LAMP5.
- chr20:9,562,941–9,577,689, 2 genes, copy number 6: AL353612.2, AL353612.1.

Autosomal genes at a single copy (total copy number 1): 82. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
